Somatic mutation profile of tumor specimen TCGA-IB-A6UG-01A (aliquot TCGA-IB-A6UG-01A-32D-A33T-08) from TCGA case TCGA-IB-A6UG, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 65.0 years (23,751 days).
Specimen TCGA-IB-A6UG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25cb9567-6e14-448e-b52f-650c1951dfb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-A6UG-10A (Blood Derived Normal), aliquot TCGA-IB-A6UG-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15aaa324-5c11-433d-872c-f35743c2684b

The open-access MAF lists 67 somatic variants for this specimen: 51 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 45, Silent 16, Nonsense Mutation 3, Splice Site 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 52/152 reads (34%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 15/153 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 40/323 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAN | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.308); catalogued as rs758892087, COSV100717447, COSV100717452; called by muse, mutect2
- ADAMTS12 | c.3495G>T p.Q1165H | Missense Mutation (SNP) | VAF 92/558 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.365); catalogued as COSV100711758; called by muse, mutect2, varscan2
- AHNAK | c.3905C>T p.P1302L | Missense Mutation (SNP) | VAF 217/1140 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as rs569137878, COSV99950001; called by muse, mutect2, varscan2
- ANKRD30A | c.3507A>T p.K1169N (on ENST00000611781; = p.K1113N on NM_052997.2) | Missense Mutation (SNP) | VAF 138/811 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs1209644461, COSV100654558; called by muse, mutect2, varscan2
- CACNA1G | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1251604128, COSV100662704; called by muse, mutect2
- CCDC191 | c.416A>T p.D139V | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99878846; called by muse, mutect2
- CFAP65 | c.4784C>A p.P1595Q | Missense Mutation (SNP) | VAF 62/647 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV100446051; called by muse, mutect2
- CNTRL | c.5509G>A p.E1837K | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99444118; called by muse, mutect2
- CREB1 | c.1024T>G p.*342Eext*4 (on ENST00000432329 / NM_134442.5; = p.*328Eext*4 on NM_004379.5 and 2 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 64/318 reads (20%) | catalogued as COSV100783650; called by muse, mutect2, varscan2
- DIO3 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 45/504 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs538885762, COSV100832334; called by muse, mutect2
- FLT4 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs768956955, COSV56113470; called by muse, mutect2, varscan2
- FMNL3 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 86/494 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs202178648; called by muse, mutect2, varscan2
- FZD3 | c.933G>T p.W311C | Missense Mutation (SNP) | VAF 60/454 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99528432; called by muse, mutect2, varscan2
- HECW2 | c.3307C>T p.P1103S | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as COSV99649293; called by muse, mutect2
- HPS1 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs947511620, COSV100282850; called by muse, mutect2, varscan2
- IRX6 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 12/184 reads (7%) | catalogued as rs554682141, COSV99306857; called by muse, mutect2
- ISLR2 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs1304784130, COSV62304266; called by muse, mutect2, varscan2
- KIF4B | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 140/685 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs774743075, COSV70528391, COSV70530194; called by muse, mutect2, varscan2
- KLK15 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 74/351 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100033077, COSV56826089; called by muse, mutect2, varscan2
- MERTK | c.2536A>G p.T846A | Missense Mutation (SNP) | VAF 35/414 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV99775430; called by muse, mutect2
- MMP16 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 54/922 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs780162250, COSV54149241; called by muse, mutect2
- MRPL15 | c.263+1G>A p.X88_splice | Splice Site (SNP) | VAF 83/524 reads (16%) | catalogued as rs770837758, COSV99477659; called by muse, mutect2, varscan2
- MYH6 | c.3452G>A p.R1151Q | Missense Mutation (SNP) | VAF 52/659 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs745406670; ClinVar: uncertain significance; called by muse, mutect2
- NACA | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 25/358 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV63267820; called by muse, mutect2
- NELL1 | c.1072-1G>T p.X358_splice | Splice Site (SNP) | VAF 47/539 reads (9%) | catalogued as COSV54333671; called by muse, mutect2
- NOS1 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1221421201, COSV100501538; called by muse, mutect2, varscan2
- PDZRN3 | c.1577A>G p.D526G | Missense Mutation (SNP) | VAF 39/516 reads (8%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); catalogued as COSV99732542; called by muse, mutect2
- PIAS4 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53681250; called by muse, mutect2
- POMC | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV53035960; called by muse, mutect2
- PRAMEF19 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 58/880 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1388182105; called by muse, mutect2
- PTPRE | c.1582G>T p.V528L | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54550356, COSV99619203; called by muse, mutect2
- RAVER1 | c.1700A>T p.H567L (on ENST00000615032; = p.P693= on NM_133452.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99533198; called by muse, mutect2, varscan2
- RIN2 | c.2170C>A p.L724M (on ENST00000255006 / NM_001242581.1; = p.L675M on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99658002; called by muse, mutect2
- RPL10L | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 98/606 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1248888333, COSV100022795; called by muse, mutect2, varscan2
- SBNO2 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376023611; called by muse, mutect2
- SFXN4 | c.869C>G p.S290C | Missense Mutation (SNP) | VAF 98/590 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.806); catalogued as rs763996289, COSV100341285; called by muse, mutect2, varscan2
- SIGLEC5 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.39); catalogued as rs776241864, COSV55780704; called by muse, mutect2, varscan2
- TENM3 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs754868094, COSV69302030; called by muse, mutect2, varscan2
- TMEM132D | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs766949843, COSV101399809; called by muse, mutect2
- TMEM198 | c.1058G>T p.C353F | Missense Mutation (SNP) | VAF 48/594 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.086); catalogued as COSV99525922; called by muse, mutect2
- TMEM52 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 28/305 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs769680411, COSV100205705; called by muse, mutect2
- TNR | c.4057C>T p.R1353W | Missense Mutation (SNP) | VAF 57/699 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1557862054, COSV54914158; called by muse, mutect2
- TRIM58 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs28361506, COSV63571276; called by muse, mutect2, varscan2
- TRPC3 | c.1142G>A p.R381H (on ENST00000379645 / NM_001366479.2; = p.R308H on NM_003305.2) | Missense Mutation (SNP) | VAF 103/623 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs201312365, COSV53374898, COSV53375138; called by muse, mutect2, varscan2
- TTC19 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.916); catalogued as COSV99890470; called by muse, mutect2
- ZNF184 | c.1984C>T p.R662* | Nonsense Mutation (SNP) | VAF 44/412 reads (11%) | catalogued as rs377450857, COSV99280138; called by muse, mutect2, varscan2
- ZNF480 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 80/777 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs201346974, COSV57995191; called by muse, mutect2, varscan2
- SUPT20HL1 | c.1957G>C p.G653R | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- CHRNB2 | c.381C>T p.Y127= | Silent (SNP) | VAF 297/827 reads (36%) | catalogued as rs201024705, COSV63807947; called by muse, mutect2, varscan2
- COL27A1 | c.3453G>A p.P1151= | Silent (SNP) | VAF 24/268 reads (9%) | catalogued as rs377713952; called by muse, mutect2
- DSC1 | c.1071T>A p.T357= | Silent (SNP) | VAF 20/208 reads (10%) | catalogued as COSV99938382; called by muse, mutect2
- DSCAM | c.2319C>T p.G773= | Silent (SNP) | VAF 62/367 reads (17%) | catalogued as rs757360658, COSV68027565; called by muse, mutect2, varscan2
- FBXL7 | c.495C>T p.N165= | Silent (SNP) | VAF 8/148 reads (5%) | catalogued as rs1213344060, COSV61641008; called by muse, mutect2
- GNAZ | c.240G>A p.S80= | Silent (SNP) | VAF 67/1394 reads (5%) | catalogued as rs143475223; called by muse, mutect2
- GRIA1 | c.2367C>T p.S789= | Silent (SNP) | VAF 46/256 reads (18%) | catalogued as rs768117586, COSV99599374; called by muse, mutect2, varscan2
- KIF1A | c.3456G>A p.P1152= | Silent (SNP) | VAF 79/318 reads (25%) | catalogued as rs777751073, COSV57486996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF6 | c.1248G>A p.A416= | Silent (SNP) | VAF 61/469 reads (13%) | catalogued as rs748097675, COSV54672814, COSV99760370; called by muse, mutect2, varscan2
- OR2AG2 | c.462G>T p.L154= | Silent (SNP) | VAF 22/374 reads (6%) | catalogued as COSV100643191; called by muse, mutect2
- PCDHA10 | c.1278G>A p.A426= | Silent (SNP) | VAF 218/955 reads (23%) | catalogued as COSV100255512; called by muse, mutect2, varscan2
- PCDHGB5 | c.2274G>A p.T758= | Silent (SNP) | VAF 217/1142 reads (19%) | catalogued as rs760681088; called by muse, mutect2, varscan2
- PDZRN3 | c.2202C>T p.D734= | Silent (SNP) | VAF 51/263 reads (19%) | catalogued as rs1208588926, COSV99732538; called by muse, mutect2, varscan2
- RIC1 | c.3030C>T p.F1010= | Silent (SNP) | VAF 100/1000 reads (10%) | catalogued as COSV52606272, COSV99318147; called by muse, mutect2, varscan2
- SCN2A | c.5316C>T p.I1772= | Silent (SNP) | VAF 127/648 reads (20%) | catalogued as rs946785343, COSV51837702, COSV51857559; called by muse, mutect2, varscan2
- SPHKAP | c.60C>T p.D20= | Silent (SNP) | VAF 61/470 reads (13%) | catalogued as rs1343548749, COSV100764602; called by muse, mutect2, varscan2
